HCMI case HCM-BROD-0223-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/87804fe2-1c07-4bcc-80c6-d225e4089ba6

Demographics
Sex at birth: male; Race: white; Year of birth: 1942; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 73.2 years (26,743 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IIB; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -18 days.
   Treatment given: Treatment type: Stereotactic Radiosurgery; Treatment intent type: Neoadjuvant; Days to treatment start: 545 days (1.5 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 647 days (1.8 years); Days to treatment end: 954 days (2.6 years).
   Recorded as not given: adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; neoadjuvant Pharmaceutical Therapy, NOS; adjuvant Targeted Molecular Therapy, for residual disease.
2. Metastasis of the skin (histology not recorded by GDC). ICD-10 code: C79.3; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 75.0 years (27,381 days); Days to diagnosis: 638 days (1.7 years).

Follow-up (2 entries)
- Days to follow up: 1,253 days (3.4 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 912.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74 kg; Height: 173 cm; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Melanoma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0223-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0223-C43-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 40; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0223-C43-06A-01-S1-HE: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0223-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0223-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
